Somatic mutation profile of tumor specimen 0DLA1W from CCDI case PBBYNI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.3 years (7,052 days).
Specimen 0DLA1W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23601dd4-1909-45c2-8f4e-d9d17ce9b569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA0X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d50c6c-11eb-40be-b1dd-a715c8801e91

The open-access MAF lists 62 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Intron 5, 3'UTR 3, Frame Shift Ins 2, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.1989C>T p.I663= | Splice Region (SNP) | VAF 627/1434 reads (44%) | catalogued as rs372838802; called by muse, mutect2, varscan2
- ASTN1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 62/2058 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs897322971; called by muse, mutect2
- ATXN3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 846/1572 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs138404351; called by mutect2, varscan2
- BATF | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 119/962 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs748744681; called by muse, mutect2, varscan2
- BRCA2 | c.1166del p.P389Rfs*10 | Frame Shift Del (DEL) | VAF 967/2318 reads (42%) | catalogued as COSV66460508; called by mutect2, pindel, varscan2
- CCR2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 324/1579 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs866454124, COSV52748666; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 474/1153 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CRB1 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 409/1348 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1470040992, COSV66333569; called by muse, mutect2, varscan2
- DNAH11 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 471/1285 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs180897552, CM140771, COSV60944662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK4 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 490/1421 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs367726606; called by muse, mutect2, varscan2
- ESF1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 152/2650 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs552526994, COSV52521183; called by muse, mutect2
- EZHIP | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 291/782 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57954795; called by muse, mutect2, varscan2
- FDFT1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 142/2480 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs371554178; called by muse, mutect2
- FGF1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 828/1391 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1305923663; called by muse, mutect2, varscan2
- GRIN3A | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 785/1596 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs1394378998, COSV100701843; called by muse, mutect2
- LMNA | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 290/563 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs140455668, CM094006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCM2 | c.2627A>G p.N876S | Missense Mutation (SNP) | VAF 544/1549 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs776700956; called by muse, mutect2, varscan2
- NLGN4X | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 134/1407 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs763458960, COSV52016642, COSV52036801; ClinVar: uncertain significance; called by muse, mutect2
- PCDHGA11 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 322/947 reads (34%) | catalogued as rs764642401, COSV53909030; called by muse, mutect2, varscan2
- RHO | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 347/688 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs538820015, COSV56212477; called by muse, mutect2, varscan2
- RUSF1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767288644; called by muse, mutect2, varscan2
- SPRR3 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 576/1916 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419197244, COSV54880793; called by muse, mutect2, varscan2
- SUV39H1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 48/615 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); catalogued as rs782424305; called by muse, mutect2
- TNN | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 546/1979 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546877646, COSV53435922; called by muse, mutect2, varscan2
- ADAMTS18 | c.1843C>G p.H615D | Missense Mutation (SNP) | VAF 78/803 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.082); called by muse, mutect2
- ARHGAP22 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 346/981 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CARD10 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 554/713 reads (78%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL5 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 276/654 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CYLC1 | c.1271dup p.D425Gfs*2 | Frame Shift Ins (INS) | VAF 420/1544 reads (27%) | called by mutect2, varscan2
- EGFL6 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 273/835 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ERF | c.519_521del p.F173_S174delinsL | In Frame Del (DEL) | VAF 165/872 reads (19%) | called by mutect2, pindel, varscan2
- EYS | c.7033C>A p.R2345S | Missense Mutation (SNP) | VAF 617/1147 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LZTS3 | c.1529G>A p.G510D (on ENST00000329152; = p.G464D on NM_001282533.2) | Missense Mutation (SNP) | VAF 42/610 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2
- PRKAR2A | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 395/1016 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- QSOX2 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 241/754 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SERGEF | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 259/1875 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC1A2 | c.1044dup p.A349Cfs*34 | Frame Shift Ins (INS) | VAF 625/1866 reads (33%) | called by mutect2, pindel, varscan2
- TEX13C | c.511T>G p.Y171D | Missense Mutation (SNP) | VAF 304/718 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ABCB9 | c.564C>T p.L188= | Silent (SNP) | VAF 282/656 reads (43%) | catalogued as rs370562274; called by muse, mutect2, varscan2
- ACAN | c.7593C>T p.S2531= (on ENST00000560601 / NM_001369268.1; = p.S2493= on NM_013227.3) | Silent (SNP) | VAF 60/1065 reads (6%) | catalogued as rs754952252; called by muse, mutect2
- APOA5 | c.153C>A p.R51= | Silent (SNP) | VAF 452/1198 reads (38%) | catalogued as rs149652056; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1746T>A p.A582= | Silent (SNP) | VAF 382/1268 reads (30%) | called by muse, mutect2, varscan2
- DACH2 | c.1786T>C p.L596= | Silent (SNP) | VAF 460/1258 reads (37%) | called by muse, mutect2, varscan2
- DNAH3 | c.3351T>C p.D1117= | Silent (SNP) | VAF 361/989 reads (37%) | called by muse, mutect2, varscan2
- ENPEP | c.1371G>A p.S457= | Silent (SNP) | VAF 387/1428 reads (27%) | catalogued as rs372915832, COSV54457110; called by muse, mutect2, varscan2
- FCGBP | c.11238C>T p.A3746= | Silent (SNP) | VAF 244/731 reads (33%) | catalogued as rs773270679; called by muse, mutect2, varscan2
- IL20 | c.42G>A p.A14= | Silent (SNP) | VAF 654/1936 reads (34%) | catalogued as rs753265887, COSV65584327; called by muse, mutect2, varscan2
- LAMA2 | c.8937G>A p.G2979= | Silent (SNP) | VAF 102/1762 reads (6%) | catalogued as rs1194078171, COSV70343949; called by muse, mutect2
- MUC2 | c.270C>T p.R90= | Silent (SNP) | VAF 507/1116 reads (45%) | catalogued as rs368859604; called by muse, mutect2, varscan2
- PPFIA4 | c.3034C>A p.R1012= (on ENST00000447715; = p.R1013= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 827/1718 reads (48%) | called by muse, mutect2, varscan2
- PTCD1 | c.472C>T p.L158= | Silent (SNP) | VAF 106/1770 reads (6%) | called by muse, mutect2
- SH2D4B | c.951C>T p.F317= (on ENST00000646907; = p.F316= on NM_207372.2) | Silent (SNP) | VAF 66/1110 reads (6%) | catalogued as rs774953296; called by muse, mutect2
- TNNI3 | c.369G>A p.T123= | Silent (SNP) | VAF 169/943 reads (18%) | catalogued as rs748164248; called by muse, mutect2, varscan2
- ADGRA1 | c.*86G>A | 3'UTR (SNP) | VAF 52/115 reads (45%) | catalogued as rs539171129; called by muse, mutect2
- ANKRD13D | c.*466G>C | 3'UTR (SNP) | VAF 525/1739 reads (30%) | catalogued as COSV57752459, COSV57752853; called by muse, mutect2, varscan2
- EMD | c.399+19G>A | Intron (SNP) | VAF 206/374 reads (55%) | catalogued as rs1210419490; called by muse, mutect2, varscan2
- GRM7 | c.-30C>T | 5'UTR (SNP) | VAF 66/1492 reads (4%) | called by muse, mutect2
- HNRNPA1 | c.1063+29G>C | Intron (SNP) | VAF 152/920 reads (17%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.*95A>T | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2
- MIER1 | c.180+33G>C | Intron (SNP) | VAF 54/857 reads (6%) | called by muse, mutect2
- PRRC2C | c.8200-315T>G | Intron (SNP) | VAF 266/494 reads (54%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 45/1418 reads (3%) | called by muse, mutect2
